Somatic mutation profile of tumor specimen C3N-03880-01 (aliquot CPT0237690007) from CPTAC case C3N-03880, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 76.1 years (27,786 days).
Specimen C3N-03880-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9fdde9a-56ca-49b2-b15a-587c944ee0d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03880-31 (Blood Derived Normal), aliquot CPT0237750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54050309-9d5d-4359-8bdc-49fe08efcc8e

The open-access MAF lists 264 somatic variants for this specimen: 167 protein-altering or splice-affecting, 64 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 64, Intron 13, Nonsense Mutation 10, Splice Site 7, RNA 7, Frame Shift Del 6, Splice Region 4, 3'UTR 4, 5'UTR 4, 3'Flank 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.2504C>G p.S835W | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs762937454, COSV62322916; called by muse, mutect2, varscan2
- ABI3 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs775807811; called by muse, mutect2, varscan2
- ADAM32 | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486618832, COSV101165448, COSV65953381; called by muse, mutect2
- ALDH2 | c.414T>A p.D138E | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.632); catalogued as COSV55669841; called by muse, mutect2
- ARID1B | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs750810656, COSV51652326; called by muse, mutect2
- ARMC4 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs770059788; called by muse, mutect2, varscan2
- BRINP2 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 28/173 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1168667936, COSV100837790; called by muse, mutect2, varscan2
- BRINP3 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66540515; called by muse, mutect2
- BRWD3 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 67/161 reads (42%) | catalogued as COSV64752867; called by muse, mutect2, varscan2
- C6 | c.-19G>T | Splice Region (SNP) | VAF 43/285 reads (15%) | catalogued as rs1005565798, COSV99666799; called by muse, mutect2, varscan2
- CDAN1 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748052163; called by muse, mutect2, varscan2
- CFAP52 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV55343331; called by muse, mutect2, varscan2
- CFAP74 | c.2994C>A p.C998* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as rs1353166583; called by muse, mutect2, varscan2
- CLN3 | c.1184G>T p.G395V (on ENST00000360019 / NM_001286104.2; = p.G419V on NM_000086.2) | Missense Mutation (SNP) | VAF 108/618 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100343466, COSV61107378; called by muse, mutect2, varscan2
- CNTN4 | c.2298C>A p.S766R | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV61870624; called by muse, mutect2
- CPNE1 | c.895C>G p.P299A (on ENST00000352393; = p.P304A on NM_003915.5) | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs758874748; called by muse, mutect2, varscan2
- CTDP1 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 122/582 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs541510090; called by muse, mutect2, varscan2
- DBX1 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1391144908; called by muse, mutect2, varscan2
- FLG | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 156/812 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs967493717, COSV64236931; called by muse, mutect2, varscan2
- FRY | c.1784+1G>A p.X595_splice | Splice Site (SNP) | VAF 28/124 reads (23%) | catalogued as COSV66572754; called by muse, mutect2, varscan2
- GAL3ST1 | c.1046G>A p.G349D | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs781484854; called by muse, mutect2
- GALNT17 | c.1017A>C p.E339D | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs766485887; called by muse, mutect2, varscan2
- IKZF2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs772378303; called by muse, mutect2, varscan2
- LMF1 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.421); catalogued as rs762677583; called by muse, varscan2
- LUZP4 | c.91+1G>C p.X31_splice | Splice Site (SNP) | VAF 43/91 reads (47%) | catalogued as COSV64219269; called by muse, mutect2, varscan2
- MAGEC1 | c.1843C>A p.P615T | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV53571872; called by muse, mutect2, varscan2
- MGAM2 | c.2362G>C p.G788R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV72176201; called by muse, mutect2, varscan2
- MGAT5 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1222220419; called by muse, mutect2
- MYO1A | c.828C>A p.N276K | Missense Mutation (SNP) | VAF 89/528 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55656362; called by muse, mutect2, varscan2
- NRG3 | c.1891G>C p.A631P (on ENST00000404547 / NM_001370084.1; = p.A607P on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV64549697; called by muse, mutect2
- OGDHL | c.2823G>A p.W941* | Nonsense Mutation (SNP) | VAF 15/226 reads (7%) | catalogued as rs1422649658; called by muse, mutect2
- OR14A16 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT tolerated (0.98); PolyPhen benign (0.036); catalogued as COSV100713657, COSV62927626; called by muse, mutect2, varscan2
- OR2T11 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764710178; called by muse, mutect2, varscan2
- OR4K14 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs759987098; called by muse, mutect2, varscan2
- OR4P4 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.039); catalogued as rs765931099, COSV100111675; called by muse, mutect2, varscan2
- P4HA2 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs1323635433; called by muse, mutect2, varscan2
- PCK1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs755135303; called by muse, mutect2, varscan2
- POLG | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 77/298 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs866985804, COSV51520612; called by muse, mutect2, varscan2
- PPP2R2C | c.1153C>G p.R385G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100160797, COSV59442732; called by muse, mutect2, varscan2
- PXDNL | c.3022del p.E1008Sfs*23 | Frame Shift Del (DEL) | VAF 88/316 reads (28%) | catalogued as COSV62487819; called by mutect2, pindel, varscan2
- RAI2 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs756566295, COSV100518535, COSV58965601; called by muse, mutect2, varscan2
- RIMS2 | c.3028A>G p.S1010G (on ENST00000666250 / NM_001348490.2; = p.S818G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.485); catalogued as rs375700279; called by muse, mutect2, varscan2
- SGCD | c.815T>A p.L272Q (on ENST00000435422 / NM_001128209.2; = p.L273Q on NM_000337.5) | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751089534; called by muse, mutect2, varscan2
- SLC17A2 | c.827G>T p.W276L | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55353985; called by muse, mutect2, varscan2
- SLC40A1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs777520713; called by muse, mutect2, varscan2
- SYT14 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV55054786; called by muse, mutect2, varscan2
- TEC | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV101202661; called by muse, mutect2, varscan2
- TP53 | c.461del p.G154Afs*16 | Frame Shift Del (DEL) | VAF 124/333 reads (37%) | catalogued as CM951223, COSV52667239, COSV52783646, COSV53625267; called by mutect2, pindel, varscan2
- WDR81 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 169/358 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs974954126; called by muse, mutect2, varscan2
- XIRP2 | c.5764G>C p.E1922Q (on ENST00000628543; = p.E2097Q on NM_152381.6) | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV54734415; called by muse, mutect2
- ZFHX4 | c.5681C>A p.S1894Y | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.081); catalogued as COSV50999512, COSV99070792; called by muse, mutect2, varscan2
- ABCA12 | c.6866T>A p.L2289H (on ENST00000272895 / NM_173076.3; = p.L1971H on NM_015657.3) | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRV1 | c.7802A>T p.Q2601L | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ALOX15B | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ANKRD18A | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CCDC141 | c.2477A>G p.H826R | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CCDC96 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- CCL20 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.231); called by muse, mutect2
- CDH10 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDK5 | c.107G>T p.R36M | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CEP192 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CHRM3 | c.753C>A p.Y251* | Nonsense Mutation (SNP) | VAF 106/281 reads (38%) | called by muse, mutect2, varscan2
- CLIP1 | c.3398del p.N1133Mfs*5 (on ENST00000620786 / NM_001247997.1; = p.N1122Mfs*5 on NM_002956.2) | Frame Shift Del (DEL) | VAF 34/125 reads (27%) | called by mutect2, varscan2
- CNTN1 | c.2864A>G p.Y955C | Missense Mutation (SNP) | VAF 66/483 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- COL22A1 | c.19A>C p.N7H | Missense Mutation (SNP) | VAF 108/451 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL24A1 | c.1546-2A>T p.X516_splice | Splice Site (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- CSRP2 | c.296G>C p.R99T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- DGKQ | c.2359A>G p.I787V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.168); called by muse, mutect2
- DNAH5 | c.11860C>A p.Q3954K | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- DPP6 | c.2414C>T p.T805I (on ENST00000377770 / NM_001364500.2; = p.T743I on NM_001936.5) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DTX1 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- FAM170B | c.111A>G p.P37= | Splice Region (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- FAM47C | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 84/260 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FLI1 | c.1294C>G p.P432A | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- FMO1 | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- GPRIN2 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 29/596 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); called by muse, mutect2
- GTF2H2C | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- HMG20B | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2
- HUWE1 | c.7547A>T p.H2516L | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IGKV1D-33 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.624); called by mutect2, varscan2
- IGKV3D-11 | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 114/640 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- IL5RA | c.1085G>T p.C362F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQGAP3 | c.907G>C p.A303P | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- IRS1 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ITSN1 | c.2869C>A p.Q957K | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT tolerated (1); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KANK4 | c.2216A>G p.H739R | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNG3 | c.1204del p.A402Hfs*34 | Frame Shift Del (DEL) | VAF 28/188 reads (15%) | called by mutect2, pindel, varscan2
- KIRREL3 | c.1032G>C p.L344F | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, varscan2
- KRT33B | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 142/925 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRBA | c.4484G>A p.G1495D | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.1480A>T p.S494C | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRRC37A2 | c.4069G>A p.G1357R | Missense Mutation (SNP) | VAF 106/3250 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- LRRC9 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ3 | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP1A | c.6950C>T p.A2317V | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MCOLN2 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MDGA2 | c.1142C>A p.A381D (on ENST00000399232 / NM_001113498.2; = p.A83D on NM_182830.4) | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MKRN3 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 56/250 reads (22%) | called by mutect2, varscan2
- MMP17 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MTTP | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUC17 | c.7569C>A p.S2523R | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MUC4 | c.2842A>T p.T948S | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- MYO10 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO1D | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYT1L | c.1484C>A p.S495* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- NEGR1 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 110/330 reads (33%) | called by muse, mutect2, varscan2
- NES | c.3727C>A p.Q1243K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NFE2L2 | c.80_106del p.D27_E35del | In Frame Del (DEL) | VAF 29/176 reads (16%) | called by mutect2, pindel
- NIBAN3 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.319); called by muse, mutect2
- NLK | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.678); called by muse, mutect2
- NLRP14 | c.2726C>T p.S909L | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NUDCD3 | c.487A>T p.R163W | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR5F1 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- OR6N2 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- OR6T1 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR9A2 | c.868A>T p.N290Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- P4HTM | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PARP8 | c.2236A>C p.M746L | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PCBP1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 40/518 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2
- PHOX2A | c.742G>C p.A248P | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PRLR | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 119/510 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- PRMT8 | c.556T>C p.W186R | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRB | c.2675G>A p.S892N | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS9BP | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 78/398 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF225 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SCN7A | c.2413C>A p.L805I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.492); called by muse, mutect2
- SHANK2 | c.484-2A>T p.X162_splice | Splice Site (SNP) | VAF 371/571 reads (65%) | called by muse, mutect2, varscan2
- SMARCA2 | c.3376A>T p.T1126S | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SNAPC4 | c.2909A>T p.Q970L | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- STIL | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- STOX1 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- STT3A | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SYNE1 | c.2863del p.D955Ifs*25 (on ENST00000367255 / NM_182961.4; = p.D962Ifs*25 on NM_033071.3) | Frame Shift Del (DEL) | VAF 33/139 reads (24%) | called by mutect2, pindel, varscan2
- SYT1 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TACC2 | c.6811G>T p.E2271* (on ENST00000334433; = p.E349* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 27/150 reads (18%) | called by muse, mutect2, varscan2
- TAP1 | c.148_161del p.P50Gfs*9 | Frame Shift Del (DEL) | VAF 27/125 reads (22%) | called by mutect2, pindel, varscan2
- TDRD15 | c.4148C>G p.S1383C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TFAP2B | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 211/369 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TIMM44 | c.260A>T p.E87V | Missense Mutation (SNP) | VAF 42/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TLE4 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TM4SF1 | c.218A>C p.D73A | Missense Mutation (SNP) | VAF 74/667 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TM6SF2 | c.298-7C>A | Splice Region (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- TMED6 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 95/397 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TMEM267 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM38B | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TNS4 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 140/582 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOPAZ1 | c.1496G>A p.C499Y | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53I11 | c.189-1G>T p.X63_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- TPR | c.4580G>T p.R1527L | Missense Mutation (SNP) | VAF 109/358 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TSHZ3 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 69/602 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- TTLL3 | c.56G>T p.R19L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); called by muse, mutect2
- TTN | c.34934C>A p.P11645Q (on ENST00000591111; = p.P10718Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/371 reads (18%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.29622G>T p.M9874I (on ENST00000591111; = p.M8947I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | PolyPhen benign (0.443); called by muse, mutect2, varscan2
- UBE2Q1 | c.588+5G>T | Splice Region (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- USP26 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- UTS2B | c.240+1G>C p.X80_splice | Splice Site (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- UVRAG | c.1027G>T p.G343C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WHAMM | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- YTHDC2 | c.1688G>C p.S563T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZADH2 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZAR1L | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF19 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF224 | c.338G>A p.R113K | Missense Mutation (SNP) | VAF 83/395 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- ZNF729 | c.2599C>T p.L867F | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804B | c.2510C>A p.T837N | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF81 | c.278-1G>T p.X93_splice | Splice Site (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- ACSBG1 | c.417C>T p.Y139= | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs748761669; called by muse, mutect2, varscan2
- AHNAK2 | c.9786G>A p.V3262= | Silent (SNP) | VAF 39/344 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.1572C>T p.S524= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV100726466; called by muse, mutect2
- ATP8B3 | c.1503G>A p.T501= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs779014211; called by muse, mutect2, varscan2
- C3orf33 | c.18G>T p.A6= | Silent (SNP) | VAF 19/438 reads (4%) | catalogued as rs1473275679; called by muse, mutect2
- CCDC58 | c.81T>C p.D27= | Silent (SNP) | VAF 66/194 reads (34%) | catalogued as rs1419911689; called by muse, mutect2, varscan2
- CDCA7 | c.126T>G p.A42= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs759103879; called by muse, mutect2, varscan2
- CEP131 | c.1779G>A p.A593= (on ENST00000269392 / NM_001319228.2; = p.A590= on NM_014984.4) | Silent (SNP) | VAF 113/284 reads (40%) | catalogued as rs747518925; called by muse, mutect2, varscan2
- CLN3 | c.1185G>T p.G395= (on ENST00000360019 / NM_001286104.2; = p.G419= on NM_000086.2) | Silent (SNP) | VAF 106/621 reads (17%) | catalogued as rs756893993; called by muse, mutect2, varscan2
- CLNK | c.1071C>T p.Y357= | Silent (SNP) | VAF 47/132 reads (36%) | called by muse, mutect2, varscan2
- COL22A1 | c.4554G>A p.G1518= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as rs763212911; called by muse, mutect2, varscan2
- CYBRD1 | c.18C>T p.Y6= | Silent (SNP) | VAF 55/340 reads (16%) | catalogued as rs771143937; called by muse, mutect2, varscan2
- CYP2A6 | c.1419G>A p.V473= | Silent (SNP) | VAF 93/591 reads (16%) | called by muse, mutect2, varscan2
- CYP2A7 | c.1419G>A p.V473= | Silent (SNP) | VAF 49/287 reads (17%) | called by muse, mutect2, varscan2
- DDTL | c.321T>C p.H107= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- DNAH11 | c.8610C>T p.Y2870= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs878854446; called by muse, mutect2, varscan2
- DNAJB2 | c.75C>T p.R25= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs1416423436; called by muse, mutect2, varscan2
- F13B | c.1053T>A p.S351= | Silent (SNP) | VAF 123/390 reads (32%) | called by muse, mutect2, varscan2
- FCRL4 | c.156A>T p.T52= | Silent (SNP) | VAF 23/316 reads (7%) | called by muse, mutect2
- FCRL5 | c.2289T>A p.A763= | Silent (SNP) | VAF 42/221 reads (19%) | called by muse, mutect2, varscan2
- GPR45 | c.189G>A p.P63= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs551427785; called by muse, mutect2, varscan2
- GREB1 | c.5028G>A p.K1676= | Silent (SNP) | VAF 92/460 reads (20%) | called by muse, mutect2, varscan2
- GRTP1 | c.42G>T p.P14= | Silent (SNP) | VAF 32/139 reads (23%) | called by muse, mutect2, varscan2
- IGLV5-48 | c.291A>T p.A97= | Silent (SNP) | VAF 24/268 reads (9%) | called by muse, mutect2
- KCNA5 | c.1017G>A p.L339= | Silent (SNP) | VAF 50/310 reads (16%) | called by muse, mutect2, varscan2
- KLF6 | c.669G>T p.T223= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as COSV51494842; called by muse, mutect2, varscan2
- LONRF3 | c.991C>T p.L331= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs754836117; called by muse, mutect2, varscan2
- MAP2 | c.5394C>T p.S1798= | Silent (SNP) | VAF 78/423 reads (18%) | catalogued as rs1195076426, COSV99557413; called by muse, mutect2, varscan2
- MYH2 | c.5085G>T p.R1695= | Silent (SNP) | VAF 267/609 reads (44%) | called by muse, mutect2, varscan2
- NAXE | c.813C>T p.Y271= | Silent (SNP) | VAF 45/426 reads (11%) | called by muse, mutect2, varscan2
- NCKIPSD | c.1740C>T p.H580= | Silent (SNP) | VAF 30/374 reads (8%) | catalogued as rs201526411; called by muse, mutect2
- NELL1 | c.1533C>T p.N511= | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as rs775236513, COSV54331191; called by muse, mutect2, varscan2
- NIFK | c.156A>T p.L52= | Silent (SNP) | VAF 85/402 reads (21%) | called by muse, mutect2, varscan2
- NLGN1 | c.1830A>T p.V610= | Silent (SNP) | VAF 37/282 reads (13%) | called by muse, mutect2, varscan2
- NXF3 | c.672G>A p.Q224= | Silent (SNP) | VAF 48/99 reads (48%) | called by muse, mutect2, varscan2
- ODF3L2 | c.645C>T p.Y215= | Silent (SNP) | VAF 27/307 reads (9%) | called by muse, mutect2
- OR4D10 | c.714C>T p.S238= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs766677789, COSV73260219; called by muse, mutect2
- OR51B2 | c.705C>A p.A235= | Silent (SNP) | VAF 19/218 reads (9%) | called by muse, mutect2
- PDK2 | c.147C>T p.S49= | Silent (SNP) | VAF 104/430 reads (24%) | catalogued as rs574384602; called by muse, varscan2
- PER1 | c.1425C>T p.A475= | Silent (SNP) | VAF 92/193 reads (48%) | called by muse, mutect2, varscan2
- PHTF1 | c.900C>T p.D300= | Silent (SNP) | VAF 84/249 reads (34%) | called by muse, mutect2, varscan2
- PPIAL4D | c.405T>A p.R135= | Silent (SNP) | VAF 155/2385 reads (6%) | called by muse, mutect2
- PPP2R1A | c.1224T>A p.I408= | Silent (SNP) | VAF 65/275 reads (24%) | called by muse, mutect2, varscan2
- PRSS36 | c.1272G>T p.A424= | Silent (SNP) | VAF 22/134 reads (16%) | called by muse, mutect2, varscan2
- RASAL1 | c.1314C>A p.R438= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- ROBO4 | c.51G>A p.L17= | Silent (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- RPE65 | c.900C>T p.L300= | Silent (SNP) | VAF 125/367 reads (34%) | called by muse, mutect2, varscan2
- RPRD2 | c.39C>T p.S13= | Silent (SNP) | VAF 34/386 reads (9%) | catalogued as rs587736605; called by muse, mutect2
- RSPO2 | c.174G>A p.K58= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- RXFP2 | c.1413T>A p.V471= | Silent (SNP) | VAF 82/212 reads (39%) | called by muse, mutect2, varscan2
- SH2B1 | c.591C>T p.N197= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs1293000641; called by muse, mutect2, varscan2
- SHANK2 | c.3528G>C p.T1176= | Silent (SNP) | VAF 623/951 reads (66%) | called by muse, mutect2, varscan2
- SLC25A19 | c.627C>T p.A209= | Silent (SNP) | VAF 271/526 reads (52%) | catalogued as rs752580419; called by muse, mutect2, varscan2
- SLC26A4 | c.507T>A p.T169= | Silent (SNP) | VAF 52/299 reads (17%) | called by muse, mutect2, varscan2
- SLC35G3 | c.429C>A p.A143= | Silent (SNP) | VAF 299/1144 reads (26%) | catalogued as rs1435905142; called by muse, mutect2, varscan2
- SMURF1 | c.915T>G p.L305= | Silent (SNP) | VAF 74/215 reads (34%) | called by muse, mutect2, varscan2
- SORCS1 | c.2745C>A p.P915= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- SPAG17 | c.432G>A p.R144= | Silent (SNP) | VAF 63/213 reads (30%) | called by muse, mutect2, varscan2
- SPIRE1 | c.1482G>T p.V494= (on ENST00000409402 / NM_001128626.2; = p.V480= on NM_020148.3) | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, mutect2, varscan2
- TACC2 | c.6810T>C p.S2270= (on ENST00000334433; = p.S348= on NM_006997.4) | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- TRAV17 | c.279C>A p.S93= | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- TSPO2 | c.36C>A p.P12= | Silent (SNP) | VAF 20/331 reads (6%) | called by muse, mutect2
- UNC80 | c.4950G>T p.T1650= | Silent (SNP) | VAF 25/203 reads (12%) | catalogued as COSV55900339; called by muse, mutect2, varscan2
- XIRP2 | c.849C>T p.D283= (on ENST00000628543; = p.D458= on NM_152381.6) | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs1016587142; called by muse, mutect2, varscan2
- ABI2 | c.286-5359T>A | Intron (SNP) | VAF 14/89 reads (16%) | called by muse, mutect2, varscan2
- AC093155.3 | c.767-978C>T | Intron (SNP) | VAF 83/450 reads (18%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+5455T>C | Intron (SNP) | VAF 37/91 reads (41%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9091G>T | Intron (SNP) | VAF 186/961 reads (19%) | catalogued as rs782453553; called by muse, mutect2, varscan2
- ADH5P5 | chr5:23977845 G>A | 5'Flank (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2, varscan2
- AGTPBP1 | c.-175C>T | 5'UTR (SNP) | VAF 34/93 reads (37%) | catalogued as rs990043025; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826463 G>T | 3'Flank (SNP) | VAF 104/255 reads (41%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826464 G>T | 3'Flank (SNP) | VAF 104/254 reads (41%) | called by muse, mutect2, varscan2
- ANKRD20A5P | n.137C>A | RNA (SNP) | VAF 46/351 reads (13%) | called by muse, mutect2, varscan2
- COL21A1 | c.1813-547G>T | Intron (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- DAO | c.-126T>A | 5'UTR (SNP) | VAF 92/285 reads (32%) | called by muse, mutect2, varscan2
- DIRC1 | n.337C>A | RNA (SNP) | VAF 44/187 reads (24%) | catalogued as rs1032481874; called by muse, mutect2, varscan2
- DNA2 | c.-94G>C | 5'UTR (SNP) | VAF 138/356 reads (39%) | catalogued as COSV64429265; called by muse, mutect2, varscan2
- DUX4L8 | n.710G>T | RNA (SNP) | VAF 34/467 reads (7%) | called by muse, varscan2
- E2F5 | chr8:85214641 G>A | 3'Flank (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99809815; called by muse, mutect2
- GVINP1 | n.6184C>T | RNA (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.500G>T | RNA (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.501G>T | RNA (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- KAZALD1 | c.*1593C>A | 3'UTR (SNP) | VAF 42/181 reads (23%) | called by muse, mutect2, varscan2
- LDLRAP1 | c.617-25G>A | Intron (SNP) | VAF 48/500 reads (10%) | called by muse, mutect2
- MEPE | c.108+1056C>A | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- MIR548M | n.18A>T | RNA (SNP) | VAF 20/43 reads (47%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1278+60G>T | Intron (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- NDUFV1 | chr11:67604474 A>G | 5'Flank (SNP) | VAF 103/283 reads (36%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2730C>G | Intron (SNP) | VAF 51/487 reads (10%) | catalogued as COSV99478407; called by muse, mutect2, varscan2
- PML | c.1710+1404C>T | Intron (SNP) | VAF 32/552 reads (6%) | catalogued as rs773258021, COSV51448345; called by muse, mutect2
- PPP1R13L | c.1354+40G>T | Intron (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- SETDB1 | c.1140+31G>A | Intron (SNP) | VAF 40/228 reads (18%) | catalogued as COSV54991432; called by muse, mutect2
- TMEM161B | c.290-1005A>T | Intron (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- TRPM5 | c.-2C>T | 5'UTR (SNP) | VAF 27/137 reads (20%) | called by muse, mutect2, varscan2
- UNC5D | c.*2538C>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- UQCRB | c.*2329C>T | 3'UTR (SNP) | VAF 32/262 reads (12%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.*67C>T | 3'UTR (SNP) | VAF 51/217 reads (24%) | catalogued as COSV99648348; called by muse, mutect2, varscan2
